ALCHEMIST case ALCH-B1QB — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/d4bb9fd6-bdd5-4604-89ed-cdb7dcb4f465

Demographics
Sex at birth: female.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 67.7 years (24,720 days).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B1QB-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B1QB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B1QB-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 25; Percent tumor nuclei: 28; Percent normal cells: 64; Percent necrosis: 0; Percent stromal cells: 11; Percent lymphocyte infiltration: 11; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 0.
- Sample ALCH-B1QB-TTR1-A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B1QB-TTR1-A-1-0-S1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 18; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 0; Percent lymphocyte infiltration: 68; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 3.
